Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7006, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7006-01A (Primary Tumor).

[page 1 of 2]
PATH.NO:

MED. REC. NO:

PATHOLOGICAL DIAGNOSIS:

- BRAIN, LEFT TEMPORAL LOBE, EXCISIONAL BIOPSY: ANAPLASTIC ASTROCYTOMA.
1. BRAIN, LEFT TEMPORAL LOBE WHITE MATTER, EXCISION: ANAPLASTIC ASTROCYTOMA.
2. BRAIN, TUMOR, EXCISION: ANAPLASTIC ASTROCYTOMA. SEE MICROSCOPIC DESCRIPTION AND COMMENT.
-

Operation/Specimen:

Clinical History and Pre-Op Dx: [REDACTED] woman with mental confusion for a couple of months. Has enhancing tumor mass deep within the left temporal lobe.

GROSS PATHOLOGY: The specimen received in fresh state for intraoperative consultation consists of two irregularly shaped pieces of somewhat gelatinous tannish-gray soft tissue measuring 0.3 and 0.4 cm. across in largest dimension, each. Smears obtained from both pieces of tissue, and remaining tissue submitted in toto in cassette 1.

INTRAOPERATIVE CONSULTATION: Left temporal lobe: high grade glioma.

Specimen 1 received next day [REDACTED] and labeled "left temporal lobe white matter", consists of three irregularly shaped fragments of brain tissue measuring 3 x 4 x 1.5 cm. in aggregate. Serially sectioned and submitted in toto in cassettes 2 and 3.

Specimen 2 received next day [REDACTED] and labeled "brain tumor", consists of several irregularly shaped fragments of tannish-gray soft tissue measuring 2 x 1.5 x 0.9 cm. in aggregate. Submitted in toto in cassette 4.

[page 2 of 2]
Sections from specimens 1 and 2 contain portions of cerebral cortex and adjacent white matter infiltrated by an astrocytic neoplasia with morphologic characteristics similar to those described for the initial specimen. There are no areas of necrosis.

COMMENT: The neoplastic process has the features of an anaplastic astrocytoma. A MIB 1 immunoperoxidase stain has been requested and further report will follow as an addendum.

Source: NCI Genomic Data Commons file 4e4302d5-6284-4614-8647-d8ff6354d169 (TCGA-DU-7006.1341BBAE-B2BF-43FB-BE7E-C49CFD28FBB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).